Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7482, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7482-01A (Primary Tumor).

Microscopic

1. 7 Sections demonstrate a mildly hypercellular glial neoplasm that is composed primarily of cells with round to oval nuclei and scant glial processes. However, classic oligodendroglioma differentiation is not seen. In addition, there are scattered moderately to markedly atypical cells seen throughout. No mitotic figures are seen and there is no microvascular proliferation or necrosis.
2. Permanent section of the posterior margin demonstrates gray matter without hypercellularity or atypical cells to suggest neoplastic infiltration.
3. Permanent section of the deep margin demonstrates gray matter without hypercellularity or atypical cells to suggest neoplastic infiltration.
4. Permanent section of the anterior margin demonstrates gray matter without hypercellularity or atypical cells to suggest neoplastic infiltration.
5. Permanent section of the superior margin demonstrates gray matter without hypercellularity or atypical cells to suggest neoplastic infiltration.
6. Permanent section of the inferior margin demonstrates gray and white matter. There is not sufficient hypercellularity and no atypical cells are seen to suggest infiltrating neoplasm.
8. Sections demonstrate gray and white matter with infiltrating neoplasm as previously described. The tumor in this area does not demonstrate significantly greater hypercellularity or atypic. Again, no mitotic figures and no microvascular proliferation or necrosis are seen.

Addendum discussion:

MIB-1 immunohistochemistry is performed on both the nonenhancing and enhancing portions of the tumor. The former demonstrates only a few scattered MIB-1 positive cells. The average index is <0.1% and the highest area is calculated at 1.6%. In contrast, the enhancing area demonstrates many MIB-1 reactive cells. In the highest areas, a labeling index of 5.0% is calculated. This level of activity is indicative of moderate proliferation coupled with the contrast enhancement is worrisome for early anaplastic progression. However, the overall histologic features are inadequate to classify this tumor as Grade III/anaplastic.

Final Addendum Diagnosis:

1. Oligoastrocytoma, low grade, oligodendroglioma predominant
2. gray matter, negative for neoplasm
3. gray matter, negative for neoplasm
4. gray matter, negative for neoplasm
5. gray matter, negative for neoplasm
6. gray and white matter, negative for neoplasm
8. oligoastrocytoma, low grade

Source: NCI Genomic Data Commons file f710d10a-e942-4c64-ac17-ac35d186531b (TCGA-HT-7482.79A1BD03-DD03-4D45-9BD6-34B246EB3294.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).